Somatic mutation profile of tumor specimen MP2PRT-PASIFJ-TMP1-A (aliquot MP2PRT-PASIFJ-TMP1-A-1-0-D-A817-36) from MP2PRT case MP2PRT-PASIFJ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.6 years (945 days).
Specimen MP2PRT-PASIFJ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 55b68f12-3163-405a-99b0-d6a1611ae0cb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASIFJ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASIFJ-NB1-A-1-0-D-A817-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c51cbb36-6512-4081-b96b-a11a8b7cfd52

The open-access MAF lists 19 somatic variants for this specimen: 18 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, In Frame Ins 1, Splice Region 1, Frame Shift Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 36/269 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- CHD5 | c.4360C>T p.R1454W | Missense Mutation (SNP) | VAF 132/353 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs768065431; called by muse, mutect2, varscan2
- DBT | c.872G>A p.R291Q | Missense Mutation (SNP) | VAF 39/412 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs775808731; called by muse, mutect2
- IRS1 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 60/560 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.435); catalogued as rs1024227751, COSV59333264, COSV59334285; called by muse, mutect2, varscan2
- MAB21L4 | c.82C>T p.R28W | Missense Mutation (SNP) | VAF 244/543 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747870693; called by muse, mutect2, varscan2
- NYAP1 | c.851C>T p.T284M | Missense Mutation (SNP) | VAF 32/769 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs760408557; called by muse, mutect2
- PTPN20 | c.1193C>T p.T398M (on ENST00000374339 / NM_001042357.4; = p.N214= on NM_015605.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 114/278 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs782166075; called by muse, mutect2, varscan2
- RUNX2 | c.1535G>A p.R512K (on ENST00000371438; = p.R490K on NM_001015051.3) | Missense Mutation (SNP) | VAF 22/273 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61845987; called by muse, mutect2
- DTHD1 | c.1583C>G p.P528R (on ENST00000456874; = p.P363R on NM_001136536.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/499 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2
- FBXO32 | c.455T>C p.V152A | Missense Mutation (SNP) | VAF 29/342 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.069); called by muse, mutect2
- IGHV1-46 | c.351del p.R117del | Frame Shift Del (DEL) | VAF 69/92 reads (75%) | called by mutect2, pindel*, varscan2
- IGKV2D-30 | chr2:89937679 TCCCACAGTGGTACAGCCCTGA>CCGGGTAGACCAAT | Missense Mutation (DEL) | VAF 10/97 reads (10%) | called by mutect2*, pindel
- IGKV3D-15 | chr2:90115401 ins CCG | In Frame Ins (INS) | VAF 12/22 reads (55%) | called by mutect2, pindel, varscan2
- IGSF3 | c.1772A>G p.E591G (on ENST00000369486 / NM_001007237.3; = p.E611G on NM_001542.4) | Missense Mutation (SNP) | VAF 235/519 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- KIAA0825 | c.300G>A p.L100= | Splice Region (SNP) | VAF 33/150 reads (22%) | called by muse, mutect2, varscan2
- NLRC3 | c.715C>A p.P239T | Missense Mutation (SNP) | VAF 22/506 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.572); called by muse, mutect2
- SPEG | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 89/917 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.874); called by muse, mutect2
- TTN | c.81493T>C p.S27165P (on ENST00000591111; = p.S19741P on NM_003319.4) | Missense Mutation (SNP) | VAF 121/339 reads (36%) | PolyPhen benign (0.186); called by muse, mutect2, varscan2
- AL353804.7 | chrX:73846340 del A | 5'Flank (DEL) | VAF 64/387 reads (17%) | called by mutect2, pindel, varscan2
